Somatic mutation profile of tumor specimen TCGA-AX-A3G6-01A (aliquot TCGA-AX-A3G6-01A-11D-A20S-09) from TCGA case TCGA-AX-A3G6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 67.6 years (24,681 days).
Specimen TCGA-AX-A3G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cda314b-3b96-4936-b7df-9e9d7c7dcc7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3G6-10A (Blood Derived Normal), aliquot TCGA-AX-A3G6-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deaaaf99-d504-4010-b9ca-5979baedeb1c

The open-access MAF lists 59 somatic variants for this specimen: 50 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 41, Silent 9, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 27/33 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339631701, CD110165, CM110135, CX983284, COSV64289692, COSV64297668, COSV64311547; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100583967, COSV100584609; called by muse, mutect2, varscan2
- ADAMTS12 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs796498894, COSV100711673; called by muse, mutect2, varscan2
- AMIGO3 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1237596292, COSV57539411; called by muse, mutect2, varscan2
- AP1M2 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99141046; called by muse, mutect2, varscan2
- ARID1A | c.1841C>G p.S614* | Nonsense Mutation (SNP) | VAF 42/88 reads (48%) | catalogued as COSV61370682, COSV61388619, COSV61391065; called by muse, mutect2, varscan2
- BRPF1 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100121421; called by muse, mutect2, varscan2
- CD48 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs372863860, COSV63567587; called by muse, mutect2, varscan2
- CFH | c.1817C>A p.P606H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100810175; called by muse, mutect2, varscan2
- CNGA4 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101171878; called by muse, mutect2, varscan2
- CNTNAP2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.105); catalogued as COSV100672543; called by muse, mutect2, varscan2
- COL6A2 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201854898, COSV52425683; called by muse, mutect2, varscan2
- CWH43 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs771090704, COSV56944501, COSV99893297; called by muse, mutect2, varscan2
- DHRS4L2 | c.461C>A p.P154Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632639, COSV58729305; called by muse, mutect2, varscan2
- DISP2 | c.4108G>A p.G1370R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs748707092, COSV99140514; called by muse, mutect2, varscan2
- ECEL1 | c.1936A>G p.K646E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100459018; called by muse, mutect2, varscan2
- FAT2 | c.12881G>A p.G4294D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1235591397, COSV99944084; called by muse, mutect2, varscan2
- FOXA2 | c.697T>A p.W233R (on ENST00000377115 / NM_153675.3; = p.W239R on NM_021784.5) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65796771; called by muse, mutect2, varscan2
- HERC1 | c.7662T>G p.H2554Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV101496900; called by mutect2, varscan2
- LPA | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100308050; called by muse, mutect2, varscan2
- MAN2B2 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99578054; called by muse, mutect2, varscan2
- MCCC1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs569042803, COSV55607496; called by muse, mutect2, varscan2
- MED12L | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56374716, COSV56376808; called by muse, mutect2, varscan2
- NFE2L2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101229442; called by muse, mutect2, varscan2
- NOS1 | c.1211C>G p.T404R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV100501401; called by muse, mutect2
- PCSK2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99360702; called by muse, mutect2, varscan2
- PKHD1L1 | c.2965T>C p.W989R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752085441, COSV101006819; called by muse, mutect2, varscan2
- PLEKHA6 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs746433483, COSV99692749; called by muse, mutect2, varscan2
- PTPRF | c.5359G>A p.A1787T | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63443940, COSV63444954; called by muse, mutect2, varscan2
- RAD50 | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546479838, COSV54754663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASEF | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs1470025089, COSV64586492; called by muse, mutect2, varscan2
- RBM45 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53720754, COSV99618018; called by muse, mutect2, varscan2
- RILPL1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs749817152, COSV100526221; called by muse, mutect2, varscan2
- RRP8 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV99602054; called by muse, mutect2, varscan2
- SACS | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs777286357, COSV101207724; called by muse, mutect2, varscan2
- SEC24D | c.1420A>G p.K474E | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV99756794; called by muse, mutect2, varscan2
- SLC25A30 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100181424; called by muse, mutect2, varscan2
- SPNS2 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs779468163, COSV61231772; called by muse, mutect2, varscan2
- SPTBN5 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV100312156; called by muse, mutect2
- TAF1 | c.2545C>T p.R849C (on ENST00000373790 / NM_138923.4; = p.R870C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52109893; called by muse, mutect2, varscan2
- TMEM131L | c.4162C>T p.P1388S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV99548125; called by muse, mutect2, varscan2
- TNPO2 | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100790413; called by muse, mutect2
- TPBG | c.221_222del p.T74Sfs*5 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1562153860; called by pindel, varscan2
- TTN | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | PolyPhen possibly damaging (0.517); catalogued as COSV100629607, COSV60134730; called by muse, mutect2, varscan2
- UBA7 | c.945T>A p.D315E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100339852; called by muse, varscan2
- VSX1 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1349520007, COSV100942209; called by muse, mutect2
- ARHGAP5 | c.163dup p.S55Ffs*4 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- CYP4F3 | c.702_703del p.R235Tfs*17 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.1645_1669del p.L549Nfs*2 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- TP53 | c.467_470del p.R156Pfs*13 | Frame Shift Del (DEL) | VAF 18/25 reads (72%) | called by mutect2, pindel, varscan2
- ADNP2 | c.1554G>A p.G518= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100081207; called by muse, mutect2, varscan2
- COL6A2 | c.43C>T p.L15= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100154237, COSV56000565; called by muse, mutect2, varscan2
- H2BC4 | c.57G>A p.V19= | Silent (SNP) | VAF 98/136 reads (72%) | catalogued as rs757930563, COSV100020073; called by muse, mutect2, varscan2
- MYH7 | c.1815C>T p.V605= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs759226950, COSV100806632; called by muse, mutect2, varscan2
- NPNT | c.1185G>A p.L395= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99975464; called by muse, mutect2, varscan2
- OR14C36 | c.705C>T p.A235= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs759165430, COSV100507556; called by muse, mutect2, varscan2
- SLC30A4 | c.765C>A p.T255= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99970423; called by muse, mutect2
- SORCS1 | c.2730G>A p.T910= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs771876529, COSV53841529; called by muse, mutect2, varscan2
- TEDC2 | c.1008C>T p.P336= | Silent (SNP) | VAF 33/42 reads (79%) | catalogued as COSV100709743; called by muse, mutect2, varscan2
